Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A0RI, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A0RI-01A (Primary Tumor).

[page 1 of 2]
Carcinoma, infiltrating ductal, NOS

Path: Site Code: Breast, upper outer quadrant 8500/3
C50.4

Patient: CQCF - Breast, NOS C50.4 1/17/11 lw

Surgical

Surg Path

CLINICAL HISTORY:

Not provided.

GROSS EXAMINATION:

Estrogen receptor tissue sent for estrogen and progesterone receptor.

A. "Tru-cut breast biopsy.": Received fresh. The specimen is a 1 cm x 0.1 cm tan piece of breast tissue. This frozen as frozen section AF1. The frozen section remnant consists of two pieces of tan tissue measuring 0.8 x 0.1 x 0.1 and 0.7 x 0.1 x 0.1 cm. They are submitted in toto in Block A1.

B. "Right breast.": Received fresh. The specimen consists of breast with an overlying ellipse of skin. The overall dimensions of the specimen are 15 x 11 x 2 cm with an attached axillary tail which in addition measures 7.8 x 3.5 cm. The skin ellipse measures 11.5 x 4 cm in greatest dimensions. And contains a nipple at its center. The deep surgical margin is inked blue and the lateral surgical margins are inked black. Several sections have been made through the deep aspect of of the specimen revealing a 1.5 x 2.8 x 1.0 cm firm mass which radially retracts the adjacent breast tissue and which is located approximately 0.2 cm from the deep surgical margin at one point. The mass appears located in the upper outer quadrant of the breast. Further sectioning through the specimen reveals unremarkable breast parenchyma in areas away from the tumor. Material submitted for ER/PR.

Block Summary:

B1 and B2-Closest sections of tumor to the deep surgical margin inked blue.

B3 and B4-Further sections of tumor to the deep surgical margin.

B5-Section through the nipple.

B6-Representative sampling from the upper inner quadrant.

B7-Representative sampling of the lower inner quadrant.

B8-Representative sampling of the upper outer quadrant.

B9-Representative sampling of the lower outer quadrant.

B10-Further sections through the lower outer quadrant.

The axillary tail is dissected. Tumor margin has been marked with surgical suture. These are present in zone 2 at the juncture with zone 1 and are submitted separately in Block B11.

B12-Sections of fat from zone 1 appear that no definite lymph nodes are identified in zone 1.

B13-Candidate lymph nodes from zone 2.

B14, 15 and B16-Candidate lymph nodes from zone 3.

INTRA OPERATIVE CONSULTATION:

AF1 "Tru-cut breast biopsy": infiltrating ductal carcinoma.

DIAGNOSIS:

A. "TRU CUT BREAST BIOPSY":

INFILTRATING DUCTAL CARCINOMA.

B. "RIGHT BREAST":

1. INFILTRATING DUCTAL CARCINOMA, NSABP HISTOLOGIC GRADE 3, NUCLEAR GRADE MODERATELY DIFFERENTIATED. THE TUMOR COMES WITHIN 0.2 CM OF THE DEEP MARGIN GROSSLY. THE TUMOR SIZE IS 1.5 X 2.8 X 1.0 CM. VASCULAR INVASION IS PRESENT. THE TUMOR IS LOCATED IN THE UPPER OUTER QUADRANT ONLY.

HIPAA Inconsistency		☒

[page 2 of 2]
2. SIX OF FIFTEEN LYMPH NODES CONTAIN METASTATIC CARCINOMA.

Verified by:

Source: NCI Genomic Data Commons file 15af5ecb-92c8-4ad2-9061-b658a40dec7a (TCGA-B6-A0RI.F2B21F52-74F4-44C5-9991-60EBCC4E43A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).